HCMI case HCM-BROD-0108-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/035fa980-159e-4c0d-87da-d13d3dd7c17c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1951; Vital status: Dead; Days to death: 242 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C25.9; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Body of pancreas; Classification of tumor: primary; Age at diagnosis: 66.7 years (24,349 days); AJCC staging edition: 8th; AJCC clinical stage: Stage III; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Metastasis at diagnosis: No Metastasis; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 20 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 59 days; Days to treatment end: 80 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine + Nab-paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 94 days; Days to treatment end: 115 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 129 days; Days to treatment end: 171 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan Hydrochloride + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFIRINOX; Days to treatment start: 192 days; Days to treatment end: 192 days.
   Recorded as not given: adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 232 days; Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 101.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (2 samples)
- Sample HCM-BROD-0108-C25-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0108-C25-85E: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
